Somatic mutation profile of tumor specimen TCGA-AC-A6IV-01A (aliquot TCGA-AC-A6IV-01A-12D-A33E-09) from TCGA case TCGA-AC-A6IV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating lobular mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 48.0 years (17,521 days).
Specimen TCGA-AC-A6IV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91492211-9a34-4a0c-bcbd-594d560a7a77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A6IV-10A (Blood Derived Normal), aliquot TCGA-AC-A6IV-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5878d962-b7ac-455c-9e21-82caefcdb256

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Splice Site 1, 5'UTR 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as rs876658932, COSV55732282, COSV55739285; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC097636.1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200518397; called by muse, mutect2
- CREBZF | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as rs768921956, COSV52629259, COSV99476455; called by mutect2, varscan2
- LENG1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV99652271; called by muse, mutect2, varscan2
- LRP1 | c.2311G>A p.G771S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1456331427, COSV54518239; called by muse, mutect2
- PCDHA6 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as COSV65342295; called by muse, mutect2, varscan2
- PTPRD | c.3299C>T p.T1100M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs200684369, COSV61937413, COSV61956848; called by muse, mutect2, varscan2
- TMEM200A | c.532C>A p.Q178K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.874); catalogued as COSV99759874; called by muse, mutect2, varscan2
- WNK1 | c.1121T>A p.L374Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100268369, COSV60042022; called by muse, mutect2, varscan2
- XPO1 | c.2206+1G>A p.X736_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV101294290; called by muse, mutect2, varscan2
- ZP4 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.211); catalogued as COSV100850762; called by muse, mutect2, varscan2
- GATA3 | c.1330_1331del p.*444Efs*62 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- SCML4 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ZPBP | c.756C>A p.N252K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.096); called by muse, mutect2
- CHRDL2 | c.330C>A p.S110= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99734058; called by muse, varscan2
- DPP10 | c.1080T>C p.Y360= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100070900; called by muse, mutect2, varscan2
- TLR9 | c.1572G>A p.Q524= | Silent (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- TRIP11 | c.4480C>A p.R1494= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV50916350, COSV99971086; called by muse, mutect2
- EXOSC9 | c.-1C>T | 5'UTR (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99697116; called by muse, mutect2, varscan2
